Surgical pathology report (de-identified scan), TCGA case TCGA-EM-A2CM, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Health Network, specimen TCGA-EM-A2CM-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Consultation Report

ICD-0-3
Carcinoma, NOS 8010/3
Site: Thyroid, NOS C73.9 Jw 6/18/11

ICD-9 Discrepancy		☒

Specimen(s) Received

1. Thyroid: Left Subtotal Thyroid including upper mediastinal component
2. left level II
3. left level VI

Diagnosis

1. Angioinvasive poorly differentiated thyroid carcinoma, widely invasive, arising in follicular variant papillary carcinoma, 9.6 cm: Thyroid, left hemithyroidectomy specimen.
2. No pathological diagnosis: Lymph node, 1 (left level 2) dissection specimen.
3. No pathological diagnosis: Lymph nodes, 2 (left level 6) dissection specimen.

Synoptic Data

Clinical History:	No radiation exposure
Procedure:	Other: Total thyroidectomy with left levels 2 and 6 dissection
Received:	Fresh
Specimen Integrity:	Intact
Specimen Size:	Left lobe:
	9.6 cm
	7.2 cm
	3.9 cm
	Isthmus +/- pyramidal lobe:
	1.5 cm
	1.5 cm
	1.1 cm
	Central compartment:
	0.4 cm
	0.8 cm
	0.5 cm
	Additional specimen: left level 2
	0.9 cm
	0.7 cm
Specimen Weight:	201 g

[page 2 of 3]
Tumor Focality:	Unifocal
----- DOMINANT TUMOR -----	
Tumor Laterality:	Left lobe
Tumor Size:	Greatest dimension: 9.6cm Additional dimension: 7.2 cm Additional dimension: 3.9 cm
Histologic Type:	Poorly differentiated thyroid carcinomas, including insular carcinoma
Histologic Grade:	G3: Poorly differentiated
Margins:	Margins uninvolved by carcinoma
Tumor Capsule:	Partially encapsulated
Tumor Capsular Invasion:	Present, extent widely invasive
Lymph-Vascular Invasion:	Present, focal extent (less than 4 vessels)
Perineural Invasion:	Not identified
Extrathyroidal Extension:	Not identified
TNM Descriptors:	Not applicable
Primary Tumor (pT):	pT3: Tumor more than 4 cm, limited to thyroid or with minimal extrathyroidal extension (eg, extension to sternothyroid muscle or perithyroid soft tissues)
Regional Lymph Nodes (pN):	pN0: No regional lymph node metastasis Number of regional lymph nodes examined: 3 Number of regional lymph nodes involved: 0
Distant Metastasis (pM):	Not applicable

*Pathologic Staging is based on AJCC/UICC TNM, 7th Edition

Electronically

verified by:

Gross Description

1. The specimen labeled with the patient's name and as "left subtotal thyroid including upper mediastinal component" consists of a left hemithyroidectomy specimen with mediastinal fat. The specimen weighs 201 g. The lobe measures 9.6 cm SI x 7.2 cm ML x 3.9 cm AP and the isthmus measures 1.5 SI x 1.5 cm ML x 0.4 cm AP. The mediastinal fat measures 4.4 x 4 x 0.6 cm. The external surfaces have fibrous adhesions. No parathyroid glands or lymph nodes are identified grossly. The external surface is painted with silver nitrate. The entire lobe is replaced by a well-delineated nodule that exhibits fibrous septation, focal hemorrhage and a few cysts, the largest measuring 2.0 cm. The remainder of the thyroid tissue is grossly unremarkable. Sections of nodule are stored frozen. Representative sections are submitted.

1A-O lobe, superior to inferior
1P isthmus

2. The specimen labeled with the patient's name and as "left level 2" consists of lymph node that measures 0.9 x 0.7 x 0.3 cm.

2A bisected and submitted in toto

3. The specimen labeled with the patient's name and as "left level 6" consists of 2 lymph nodes that measure 0.2 x 0.2 x 0.2 cm and 2 x 0.6 x 0.3cm

3A submitted in toto

Source: NCI Genomic Data Commons file 9ee75ac0-b7ba-4d07-91c1-e094d642041a (TCGA-EM-A2CM.26C8884E-4AFB-468D-A974-BE406BD2845F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).